Somatic mutation profile of tumor specimen TCGA-74-6573-01A (aliquot TCGA-74-6573-01A-12D-1845-08) from TCGA case TCGA-74-6573, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 67.4 years (24,632 days).
Specimen TCGA-74-6573-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecae3b1e-a413-435d-a58b-c911cf0350d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-74-6573-11A (Solid Tissue Normal), aliquot TCGA-74-6573-11A-02D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/531e9f35-4b1d-43b3-abbf-9f055996a733

The open-access MAF lists 39 somatic variants for this specimen: 26 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 22, Silent 13, Nonsense Mutation 2, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1365_1367dup p.Q455_F456insL (on ENST00000521381 / NM_181523.3; = p.Q185_F186insL on NM_181504.4) | In Frame Ins (INS) | VAF 32/76 reads (42%) | hotspot (GDC flag); catalogued as COSV57139912; called by mutect2, pindel, varscan2
- TP53 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 44/55 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: drug response / pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTR6 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51841062; called by muse, mutect2, varscan2
- CFAP91 | c.1708G>A p.G570R | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.019); catalogued as rs753425361, COSV56339039, COSV99847120; called by muse, mutect2, varscan2
- COL14A1 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs771681479, COSV52847017; called by muse, mutect2, varscan2
- DPRX | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 73/158 reads (46%) | catalogued as rs150237904; called by muse, mutect2, varscan2
- F5 | c.3875C>T p.T1292I | Missense Mutation (SNP) | VAF 204/500 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as rs780542249, COSV63120358, COSV63120571; called by muse, varscan2
- FFAR3 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.588); catalogued as COSV59908673; called by muse, mutect2, varscan2
- GLIS1 | c.35G>T p.C12F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.735); catalogued as COSV56543503; called by muse, mutect2, varscan2
- GPC2 | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52783849; called by muse, mutect2, varscan2
- HTR4 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 153/379 reads (40%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.034); catalogued as rs540745040, COSV100087454, COSV58789418; called by muse, mutect2, varscan2
- KAT5 | c.1189G>A p.G397R | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV57729161; called by muse, mutect2
- KIF13A | c.2302G>T p.E768* | Nonsense Mutation (SNP) | VAF 15/78 reads (19%) | catalogued as COSV52442640, COSV52462169; called by muse, mutect2, varscan2
- LRP2 | c.427+1G>A p.X143_splice | Splice Site (SNP) | VAF 32/87 reads (37%) | catalogued as COSV55540584; called by muse, mutect2, varscan2
- MPP6 | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs894818719, COSV56035271; called by muse, mutect2, varscan2
- OCM2 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777688959, COSV57535046; called by muse, mutect2, varscan2
- OR10A3 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1288299024, COSV62459151; called by muse, mutect2, varscan2
- OR2T10 | c.274A>G p.I92V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV57896088; called by muse, mutect2, varscan2
- PIWIL2 | c.2710A>G p.T904A | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63249673; called by muse, mutect2, varscan2
- PNPLA6 | c.3359T>C p.L1120P (on ENST00000414982 / NM_001166111.2; = p.L1072P on NM_006702.5) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55373482; called by muse, mutect2, varscan2
- SORBS2 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749631099, COSV52990887; called by muse, mutect2, varscan2
- ST8SIA6 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 62/99 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748029727, COSV66465672; called by muse, mutect2, varscan2
- SYCP3 | c.246C>A p.N82K | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.046); catalogued as COSV57148190; called by muse, mutect2, varscan2
- TRAF1 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs149705933; called by muse, mutect2, varscan2
- ZBED2 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51912565; called by muse, mutect2, varscan2
- SPATA31A3 | c.790G>T p.V264F | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.88); called by mutect2, varscan2
- DOCK3 | c.2769C>T p.H923= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs773077569, COSV56502333; called by muse, mutect2, varscan2
- ELP4 | c.33C>G p.A11= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV53442651; called by muse, mutect2, varscan2
- INSR | c.3612A>G p.A1204= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV57157366; called by muse, mutect2, varscan2
- JAKMIP1 | c.1608C>T p.I536= | Silent (SNP) | VAF 87/235 reads (37%) | catalogued as rs267600201, COSV51521996; called by muse, mutect2, varscan2
- MECOM | c.1848C>T p.N616= (on ENST00000468789 / NM_001105078.4; = p.N804= on NM_004991.4) | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs140021434, COSV99246081; called by muse, mutect2, varscan2
- PDGFRB | c.2298C>A p.I766= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as COSV55800747; called by muse, mutect2, varscan2
- PILRB | c.13C>T p.L5= | Silent (SNP) | VAF 52/212 reads (25%) | catalogued as COSV60333120; called by muse, mutect2, varscan2
- RSBN1 | c.600C>G p.P200= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs767216644, COSV54730994, COSV99793424; called by muse, mutect2, varscan2
- SATL1 | c.306G>A p.V102= (on ENST00000395409; = p.V289= on NM_001012980.2) | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV60575391; called by muse, mutect2, varscan2
- SENP7 | c.417T>C p.S139= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as COSV58607843; called by muse, varscan2
- TRIOBP | c.1725C>T p.P575= | Silent (SNP) | VAF 38/320 reads (12%) | catalogued as COSV60373469; called by muse, varscan2
- WDR86 | c.225C>T p.A75= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs781326293, COSV57838036; called by muse, mutect2, varscan2
- ZNF415 | c.54T>C p.D18= | Silent (SNP) | VAF 72/154 reads (47%) | catalogued as COSV99701777; called by muse, mutect2, varscan2
